Somatic mutation profile of tumor specimen TCGA-5P-A9K6-01A (aliquot TCGA-5P-A9K6-01A-11D-A42J-10) from TCGA case TCGA-5P-A9K6, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 64.0 years (23,384 days).
Specimen TCGA-5P-A9K6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0f01655-5c50-4c11-ac7b-e494fbdca7a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5P-A9K6-10A (Blood Derived Normal), aliquot TCGA-5P-A9K6-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c591311c-3926-4161-985f-bfb062d1cae6

The open-access MAF lists 54 somatic variants for this specimen: 41 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 12, Nonsense Mutation 3, Frame Shift Ins 3, Frame Shift Del 2, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY8 | c.1273A>T p.N425Y | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV99653532; called by muse, mutect2
- ALOX12B | c.607T>C p.S203P | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV100047519; called by muse, mutect2, varscan2
- ALS2 | c.3024G>T p.L1008F | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99969798; called by muse, mutect2, varscan2
- AP2A2 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV100173207; called by muse, mutect2, varscan2
- B4GALNT3 | c.2804A>T p.K935M | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99843400; called by muse, mutect2, varscan2
- BCLAF3 | c.1291T>G p.S431A | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as COSV100503359; called by muse, mutect2, varscan2
- BTBD7 | c.334A>C p.K112Q | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100108130; called by muse, mutect2, varscan2
- C2CD5 | c.2732G>T p.G911V | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100448933; called by muse, mutect2, varscan2
- CCM2L | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs545553537, COSV52950582; called by muse, mutect2, varscan2
- CLPSL2 | c.196T>C p.C66R | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100846319; called by muse, mutect2, varscan2
- DNAJB9 | c.622C>T p.Q208* | Nonsense Mutation (SNP) | VAF 35/72 reads (49%) | catalogued as COSV99974363; called by muse, mutect2, varscan2
- DPP10 | c.1988C>A p.S663* | Nonsense Mutation (SNP) | VAF 30/120 reads (25%) | catalogued as COSV100070038; called by muse, varscan2
- FOCAD | c.2710A>C p.I904L | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV58096091; called by muse, mutect2, varscan2
- G2E3 | c.2012C>T p.A671V | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99249815; called by muse, mutect2, varscan2
- GTF2IRD2B | c.1995G>T p.L665F | Missense Mutation (SNP) | VAF 133/469 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV100441219; called by muse, mutect2, varscan2
- HNRNPDL | c.230G>C p.G77A | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs1382265306, COSV99787182; called by muse, mutect2, varscan2
- HTATSF1 | c.1785T>G p.N595K | Missense Mutation (SNP) | VAF 106/148 reads (72%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.08); catalogued as COSV99511829; called by muse, mutect2, varscan2
- MAPK1 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53184719, COSV99308132; called by muse, mutect2, varscan2
- METTL16 | c.30A>C p.R10S | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99563660; called by muse, mutect2, varscan2
- NNT | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.529); catalogued as rs779012961, COSV99239319; called by muse, mutect2, varscan2
- NOP58 | c.1316G>C p.C439S | Missense Mutation (SNP) | VAF 168/522 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99970757; called by muse, mutect2, varscan2
- PRAG1 | c.1307C>A p.A436E | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.36); catalogued as COSV100422571; called by muse, mutect2, varscan2
- PRR30 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV99574708; called by muse, mutect2, varscan2
- PTGER4 | c.664T>C p.S222P | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.625); catalogued as COSV100201691, COSV56721012; called by muse, mutect2, varscan2
- RALGPS2 | c.1346T>A p.L449* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as COSV100860623; called by muse, mutect2, varscan2
- RFX5 | c.953A>G p.N318S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99057108; called by muse, mutect2
- RMC1 | c.1155A>C p.E385D | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99340339; called by muse, mutect2, varscan2
- SLC22A7 | c.901T>C p.C301R (on ENST00000372585 / NM_153320.2; = p.C299R on NM_006672.3) | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99240503; called by muse, mutect2, varscan2
- SYNE1 | c.18739C>A p.L6247I (on ENST00000367255 / NM_182961.4; = p.L6176I on NM_033071.3) | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV99573685; called by muse, mutect2, varscan2
- TEX14 | c.2556G>T p.K852N (on ENST00000240361 / NM_001201457.2; = p.K846N on NM_031272.5) | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.162); catalogued as COSV99541390; called by muse, mutect2, varscan2
- TGFB1I1 | c.1042G>T p.G348C (on ENST00000394863 / NM_001042454.3; = p.G331C on NM_015927.4) | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100691172; called by muse, mutect2, varscan2
- TOM1L1 | c.367A>G p.I123V | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.153); catalogued as COSV100779295; called by muse, mutect2, varscan2
- TPH1 | c.422A>G p.Y141C | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1405105810, COSV100001003; called by muse, mutect2, varscan2
- TRIM42 | c.2047A>C p.N683H | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99648657; called by muse, mutect2, varscan2
- ZBED1 | c.1916C>T p.A639V | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.659); catalogued as rs756381297; called by muse, mutect2
- C19orf18 | c.473del p.G158Vfs*34 | Frame Shift Del (DEL) | VAF 23/87 reads (26%) | called by mutect2, pindel, varscan2
- ECD | c.206-2_210delinsCG p.X69_splice | Splice Site (DEL) | VAF 53/204 reads (26%) | called by pindel, varscan2*
- HMGCS2 | c.822del p.I277Sfs*22 | Frame Shift Del (DEL) | VAF 21/93 reads (23%) | called by mutect2, pindel, varscan2
- LRP2 | c.13095dup p.E4366* | Frame Shift Ins (INS) | VAF 16/58 reads (28%) | called by mutect2, pindel, varscan2
- PKN3 | c.1603_1604dup p.M535Ifs*29 | Frame Shift Ins (INS) | VAF 36/144 reads (25%) | called by mutect2, pindel, varscan2
- TEDC1 | c.423_424insA p.C142Mfs*4 | Frame Shift Ins (INS) | VAF 6/29 reads (21%) | called by mutect2, varscan2
- ACSS1 | c.666A>G p.G222= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV100053919; called by muse, mutect2, varscan2
- AP2S1 | c.390G>A p.K130= | Silent (SNP) | VAF 33/87 reads (38%) | catalogued as COSV99617488; called by muse, mutect2, varscan2
- COG4 | c.999G>A p.Q333= | Silent (SNP) | VAF 46/93 reads (49%) | catalogued as COSV100092094; called by muse, mutect2, varscan2
- EIF4G1 | c.2739G>A p.E913= (on ENST00000346169 / NM_198241.3; = p.E718= on NM_004953.5) | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as COSV100072150; called by muse, mutect2, varscan2
- INPP5F | c.2724T>C p.L908= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV100740297; called by muse, mutect2, varscan2
- KRT84 | c.834C>T p.F278= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV99230991; called by muse, mutect2, varscan2
- MYH10 | c.1821G>A p.L607= | Silent (SNP) | VAF 44/81 reads (54%) | catalogued as COSV99345926; called by muse, mutect2, varscan2
- NKX3-2 | c.927C>T p.P309= | Silent (SNP) | VAF 84/318 reads (26%) | catalogued as COSV101219950; called by muse, mutect2, varscan2
- OR4E2 | c.393C>T p.H131= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV100330133; called by muse, varscan2
- SMCHD1 | c.3024G>A p.T1008= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as rs781311866, COSV99862204; called by muse, mutect2, varscan2
- ZNF562 | c.1095T>C p.N365= (on ENST00000453372 / NM_001130032.2; = p.N293= on NM_017656.4) | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as COSV99530808; called by muse, mutect2, varscan2
- ZPR1 | c.768C>T p.S256= | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as COSV99911424; called by muse, mutect2, varscan2
- RUFY3 | chr4:70794867 G>A | 3'Flank (SNP) | VAF 46/129 reads (36%) | catalogued as COSV99887699; called by muse, mutect2, varscan2
